Somatic mutation profile of tumor specimen d3078fa8-0692-411f-8441-0c7c48 (aliquot d3078fa8-0692-411f-8441-0c7c48_D6_1) from CPTAC case 11CO058, project CPTAC-2 (Colon — Adenomas and Adenocarcinomas). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIA.
Specimen d3078fa8-0692-411f-8441-0c7c48: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1ab081b1-7b69-423c-be60-8e8439b87b0e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen b2642bf8-c902-49cd-a765-59c718 (Blood Derived Normal), aliquot b2642bf8-c902-49cd-a765-59c718_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5431f7a8-da52-425b-ab87-1caf878982a8

The open-access MAF lists 109 somatic variants for this specimen: 78 protein-altering or splice-affecting, 18 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 63, Silent 18, Nonsense Mutation 6, RNA 5, Intron 4, Splice Region 3, Frame Shift Ins 2, 3'UTR 2, Splice Site 2, 5'UTR 2, Frame Shift Del 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.2805C>A p.Y935* | Nonsense Mutation (SNP) | VAF 36/251 reads (14%) | hotspot (GDC flag); catalogued as rs137854575, CD041148, CM920044, CM970086, COSV57324059, COSV57328770; ClinVar: pathogenic; called by muse, varscan2
- APC | c.4463del p.L1488Yfs*19 | Frame Shift Del (DEL) | VAF 26/65 reads (40%) | catalogued as rs1114167577, COSV57389473; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- KRAS | c.182A>T p.Q61L | Missense Mutation (SNP) | VAF 55/133 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.631); catalogued as rs121913240, COSV55498739, COSV55504296, COSV55508574; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- MYBPC3 | c.3373G>A p.V1125M | Missense Mutation (SNP) | VAF 45/220 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as rs121909378, CM116880; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- ANKLE1 | c.1724G>A p.R575H (on ENST00000394458; = p.R521H on NM_152363.6) | Missense Mutation (SNP) | VAF 87/313 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.073); catalogued as rs745821293, COSV66730992; called by muse, mutect2, varscan2
- ATN1 | c.2403G>C p.E801D | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.869); catalogued as COSV63110825; called by muse, mutect2, varscan2
- BICD2 | c.2109G>A p.T703= | Splice Region (SNP) | VAF 64/181 reads (35%) | catalogued as rs1243854107; called by muse, mutect2, varscan2
- BIRC7 | c.643G>A p.E215K | Missense Mutation (SNP) | VAF 40/325 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.376); catalogued as COSV53901468; called by muse, mutect2, varscan2
- BOC | c.1358C>T p.T453M | Missense Mutation (SNP) | VAF 84/299 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.069); catalogued as rs765600285, COSV99849034; called by muse, mutect2
- CACNA1E | c.4780C>T p.R1594C | Missense Mutation (SNP) | VAF 25/98 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1375830903; called by muse, mutect2, varscan2
- CFAP299 | c.448dup p.R150Kfs*17 | Frame Shift Ins (INS) | VAF 14/32 reads (44%) | catalogued as rs761800837; called by mutect2, varscan2
- CNTNAP5 | c.457C>T p.R153C | Missense Mutation (SNP) | VAF 67/272 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV101442996; called by muse, mutect2, varscan2
- CXCR5 | c.463G>A p.V155I | Missense Mutation (SNP) | VAF 107/532 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0.1); catalogued as rs377218103; called by muse, mutect2, varscan2
- DHDH | c.379C>T p.R127C | Missense Mutation (SNP) | VAF 55/163 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs865845501, COSV55481497, COSV55483348; called by muse, mutect2, varscan2
- DLGAP2 | c.2245C>T p.R749W | Missense Mutation (SNP) | VAF 32/138 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as rs904926499, COSV70098064, COSV70098970; called by muse, mutect2, varscan2
- DMD | c.10105G>A p.V3369I | Missense Mutation (SNP) | VAF 41/258 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.486); catalogued as CD100305; called by muse, mutect2, varscan2
- DOCK2 | c.3821G>A p.R1274Q | Missense Mutation (SNP) | VAF 88/330 reads (27%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.711); catalogued as rs145262338, COSV99915170; called by muse, varscan2
- FAM183A | c.319C>T p.R107C | Missense Mutation (SNP) | VAF 76/245 reads (31%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.555); catalogued as rs763260830, COSV58922006; called by muse, mutect2, varscan2
- GABRR2 | c.896C>T p.T299M | Missense Mutation (SNP) | VAF 27/143 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.409); catalogued as rs371695052, COSV68765388; called by muse, mutect2, varscan2
- GALNT9 | c.943G>A p.E315K | Missense Mutation (SNP) | VAF 53/351 reads (15%) | SIFT tolerated (0.75); PolyPhen benign (0.207); catalogued as rs782073701, COSV61096457; called by muse, mutect2, varscan2
- GK | c.660C>T p.C220= | Splice Region (SNP) | VAF 42/167 reads (25%) | catalogued as rs765415598, COSV66736258; called by muse, mutect2, varscan2
- IGHG3 | c.202G>A p.V68M | Missense Mutation (SNP) | VAF 120/709 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.011); catalogued as rs201033566; called by muse, mutect2, varscan2
- KMT2D | c.1112+1G>A p.X371_splice | Splice Site (SNP) | VAF 9/216 reads (4%) | catalogued as COSV56434808, COSV56464081; called by muse, mutect2
- KRT222 | c.337C>T p.R113C | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.545); catalogued as rs147867384; called by muse, mutect2, varscan2
- LRP4 | c.4231C>T p.R1411* | Nonsense Mutation (SNP) | VAF 78/220 reads (35%) | catalogued as rs1276522994, COSV66138571; called by muse, mutect2, varscan2
- LRRTM4 | c.914C>T p.S305F | Missense Mutation (SNP) | VAF 11/173 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV101297412; called by muse, mutect2
- MAB21L2 | c.803C>T p.P268L | Missense Mutation (SNP) | VAF 144/361 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.093); catalogued as COSV58260725; called by muse, mutect2, varscan2
- MYORG | c.1480G>A p.A494T | Missense Mutation (SNP) | VAF 20/525 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV52626321; called by muse, mutect2
- OBSL1 | c.3883G>A p.G1295R | Missense Mutation (SNP) | VAF 76/300 reads (25%) | SIFT tolerated (0.51); PolyPhen benign (0.267); catalogued as rs530576939; called by muse, mutect2, varscan2
- OR10AG1 | c.276G>A p.M92I | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.031); catalogued as COSV56633872; called by muse, mutect2, varscan2
- PCDHB16 | c.811G>A p.G271S | Missense Mutation (SNP) | VAF 18/436 reads (4%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0); catalogued as COSV53361604; called by muse, mutect2
- PEAR1 | c.2825G>A p.S942N | Missense Mutation (SNP) | VAF 12/321 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.638); catalogued as COSV99442219; called by muse, mutect2
- PGBD5 | c.892C>T p.R298C (on ENST00000525115; = p.R367C on NM_001258311.2) | Missense Mutation (SNP) | VAF 96/344 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs1327319064, COSV58412896; called by muse, mutect2, varscan2
- POLR1A | c.301C>T p.R101W | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55692085; called by muse, mutect2, varscan2
- PROSER2 | c.1241G>A p.R414H | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1306771682; called by muse, mutect2, varscan2
- PXDNL | c.2333C>T p.P778L | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773684857; called by muse, mutect2, varscan2
- RIBC1 | c.296G>A p.R99Q | Missense Mutation (SNP) | VAF 148/382 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.488); catalogued as COSV99394990; called by muse, mutect2, varscan2
- ROBO3 | c.338C>T p.A113V | Missense Mutation (SNP) | VAF 70/214 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); catalogued as rs1212808083, COSV67300716; called by muse, mutect2, varscan2
- SAP130 | c.2758G>A p.V920I | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.003); catalogued as rs368212529; called by muse, mutect2, varscan2
- SCN11A | c.2174G>A p.R725H | Missense Mutation (SNP) | VAF 22/140 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs752954989; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCN7A | c.1309G>C p.E437Q | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.946); catalogued as COSV69274827, COSV69274854; called by muse, mutect2, varscan2
- SOX9 | c.523C>T p.Q175* | Nonsense Mutation (SNP) | VAF 93/378 reads (25%) | catalogued as COSV55427646; called by muse, mutect2, varscan2
- STAT4 | c.1198C>T p.R400* | Nonsense Mutation (SNP) | VAF 13/41 reads (32%) | catalogued as COSV61828430; called by muse, mutect2, varscan2
- TARM1 | c.161C>T p.T54M (on ENST00000616041 / NM_001330650.1; = p.T46M on NM_001135686.3) | Missense Mutation (SNP) | VAF 78/232 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.052); catalogued as rs774807581, COSV101444627, COSV71524833; called by muse, varscan2
- TBL2 | c.335G>A p.R112H | Missense Mutation (SNP) | VAF 60/198 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370483599; called by muse, mutect2, varscan2
- TMC5 | c.1067C>T p.S356F (on ENST00000396229 / NM_001105248.1; = p.S110F on NM_024780.5) | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.119); catalogued as COSV54903668; called by muse, varscan2
- TRPM2 | c.4060C>T p.R1354W | Missense Mutation (SNP) | VAF 77/186 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs138685995; called by muse, mutect2, varscan2
- TSC22D3 | c.227C>T p.P76L | Missense Mutation (SNP) | VAF 53/385 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.29); catalogued as rs749179992; called by muse, mutect2, varscan2
- TSHZ3 | c.2170G>A p.A724T | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs757158860, COSV53676425; called by muse, mutect2, varscan2
- TTC25 | c.157C>T p.R53C | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782472920; called by muse, mutect2, varscan2
- WSCD2 | c.137C>T p.S46L | Missense Mutation (SNP) | VAF 30/217 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as rs1461462062; called by muse, mutect2, varscan2
- ALDH18A1 | c.239C>G p.A80G | Missense Mutation (SNP) | VAF 92/271 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CADPS2 | c.1821A>C p.K607N | Missense Mutation (SNP) | VAF 37/191 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.005); called by muse, varscan2
- CAMSAP2 | c.4070G>A p.S1357N (on ENST00000236925 / NM_001297707.2; = p.S1346N on NM_203459.3) | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by mutect2, varscan2
- CCDC168 | c.1154G>T p.G385V | Missense Mutation (SNP) | VAF 40/163 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); called by muse, mutect2, varscan2
- CDH22 | c.1597C>T p.R533C | Missense Mutation (SNP) | VAF 52/380 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.545); called by muse, mutect2, varscan2
- CLCN4 | c.1035G>A p.W345* | Nonsense Mutation (SNP) | VAF 35/328 reads (11%) | called by muse, mutect2, varscan2
- ENTPD6 | c.673+1G>A p.X225_splice | Splice Site (SNP) | VAF 85/204 reads (42%) | called by muse, mutect2, varscan2
- FLG2 | c.1136G>T p.C379F | Missense Mutation (SNP) | VAF 48/598 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.049); called by muse, mutect2
- FRZB | c.213G>T p.Q71H | Missense Mutation (SNP) | VAF 89/569 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GPI | c.277A>G p.T93A | Missense Mutation (SNP) | VAF 38/263 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.29); called by muse, mutect2, varscan2
- HUWE1 | c.3602C>A p.A1201D | Missense Mutation (SNP) | VAF 73/279 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- ITPR3 | c.5938C>T p.P1980S | Missense Mutation (SNP) | VAF 62/369 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- MAST3 | c.1949G>A p.R650Q | Missense Mutation (SNP) | VAF 77/281 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.32); called by muse, mutect2, varscan2
- MPI | c.16+7C>T | Splice Region (SNP) | VAF 33/121 reads (27%) | called by muse, mutect2, varscan2
- MTARC1 | c.949T>C p.Y317H | Missense Mutation (SNP) | VAF 12/244 reads (5%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.996); called by muse, mutect2
- MTMR1 | c.1195C>T p.R399W | Missense Mutation (SNP) | VAF 8/181 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.582); called by muse, mutect2
- MYH13 | c.4445G>T p.S1482I | Missense Mutation (SNP) | VAF 19/117 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- OR10AG1 | c.346G>C p.A116P | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- OR3A3 | c.3G>C p.M1? | Translation Start Site (SNP) | VAF 11/52 reads (21%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- PABPC4L | c.784dup p.V262Gfs*13 | Frame Shift Ins (INS) | VAF 22/111 reads (20%) | called by mutect2, pindel, varscan2
- PTPRF | c.1270A>G p.M424V | Missense Mutation (SNP) | VAF 109/496 reads (22%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- RTL9 | c.2636C>A p.T879K | Missense Mutation (SNP) | VAF 62/582 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.393); called by muse, mutect2
- SENP2 | c.1366C>T p.R456* | Nonsense Mutation (SNP) | VAF 43/140 reads (31%) | called by muse, mutect2, varscan2
- SLC25A43 | c.262G>A p.A88T | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.42); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- TRIM42 | c.1616T>A p.M539K | Missense Mutation (SNP) | VAF 16/400 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.003); called by muse, mutect2
- ZFP82 | c.79C>A p.Q27K | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.622); called by muse, mutect2, varscan2
- ZNF160 | c.2020G>A p.E674K | Missense Mutation (SNP) | VAF 23/147 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- ADAMTS15 | c.1191C>T p.I397= | Silent (SNP) | VAF 75/239 reads (31%) | catalogued as rs369731938; called by muse, mutect2, varscan2
- CDH11 | c.1794C>T p.N598= | Silent (SNP) | VAF 192/565 reads (34%) | catalogued as rs563299959, COSV51764281, COSV51767424; called by muse, mutect2, varscan2
- CSMD1 | c.10113C>T p.P3371= (on ENST00000520002; = p.P3370= on NM_033225.6) | Silent (SNP) | VAF 46/150 reads (31%) | catalogued as rs374654290, COSV100144065; called by muse, mutect2, varscan2
- CSPG4 | c.2259C>T p.Y753= | Silent (SNP) | VAF 50/245 reads (20%) | catalogued as rs762097413, COSV57897182; called by mutect2, varscan2
- FAM47A | c.639G>A p.P213= | Silent (SNP) | VAF 39/191 reads (20%) | catalogued as rs754898268, COSV60496639; called by muse, mutect2, varscan2
- HHIPL1 | c.105G>T p.P35= | Silent (SNP) | VAF 29/88 reads (33%) | called by muse, varscan2
- LRRC38 | c.771C>T p.A257= | Silent (SNP) | VAF 160/392 reads (41%) | catalogued as rs977736217, COSV65791128; called by muse, mutect2
- MVB12B | c.642C>T p.T214= | Silent (SNP) | VAF 20/155 reads (13%) | called by muse, mutect2, varscan2
- NKX1-1 | c.210G>A p.A70= | Silent (SNP) | VAF 10/18 reads (56%) | called by muse, varscan2
- OBSCN | c.18681G>A p.A6227= | Silent (SNP) | VAF 61/188 reads (32%) | catalogued as rs369201561; called by muse, mutect2, varscan2
- OGDHL | c.1041C>T p.R347= | Silent (SNP) | VAF 18/348 reads (5%) | catalogued as rs756155759, COSV65103581; called by muse, mutect2
- PGA5 | c.813C>T p.G271= | Silent (SNP) | VAF 78/461 reads (17%) | called by muse, mutect2, varscan2
- RTL1 | c.1032G>A p.P344= | Silent (SNP) | VAF 69/325 reads (21%) | catalogued as rs1198505814, COSV101128301; called by muse, mutect2, varscan2
- SLC41A1 | c.231C>T p.D77= | Silent (SNP) | VAF 115/427 reads (27%) | catalogued as rs750979273; called by muse, mutect2, varscan2
- SOGA3 | c.2256C>T p.D752= | Silent (SNP) | VAF 30/129 reads (23%) | called by muse, mutect2, varscan2
- SUGP1 | c.444C>T p.H148= | Silent (SNP) | VAF 59/217 reads (27%) | catalogued as rs775713772; called by muse, mutect2, varscan2
- TFAP2D | c.393G>A p.R131= | Silent (SNP) | VAF 92/477 reads (19%) | catalogued as rs1446321755; called by muse, mutect2, varscan2
- TLNRD1 | c.417C>T p.G139= | Silent (SNP) | VAF 19/59 reads (32%) | called by muse, mutect2, varscan2
- CTTN | c.*1164C>T | 3'UTR (SNP) | VAF 19/76 reads (25%) | catalogued as rs372830860, COSV100097447; called by muse, mutect2, varscan2
- DENND10P1 | n.893C>T | RNA (SNP) | VAF 67/553 reads (12%) | catalogued as rs1285251968; called by muse, mutect2, varscan2
- EIF3IP1 | n.540G>T | RNA (SNP) | VAF 36/185 reads (19%) | called by muse, mutect2, varscan2
- FRMD8P1 | n.1028G>A | RNA (SNP) | VAF 126/547 reads (23%) | called by mutect2, varscan2
- FUNDC1 | c.*10T>C | 3'UTR (SNP) | VAF 24/67 reads (36%) | called by muse, mutect2, varscan2
- HEXD | c.982+354G>A | Intron (SNP) | VAF 10/197 reads (5%) | catalogued as rs1011272527; called by muse, mutect2
- KIF16B | c.-17C>T | 5'UTR (SNP) | VAF 25/208 reads (12%) | catalogued as rs982750614; called by muse, mutect2, varscan2
- NHSL2 | c.-92G>A | 5'UTR (SNP) | VAF 57/371 reads (15%) | catalogued as rs760149925, COSV101030003; called by muse, mutect2, varscan2
- OVCH1-AS1 | n.294G>A | RNA (SNP) | VAF 35/79 reads (44%) | catalogued as rs376021929; called by muse, mutect2, varscan2
- OVCH1-AS1 | n.403G>A | RNA (SNP) | VAF 41/310 reads (13%) | catalogued as rs1226572916; called by muse, mutect2, varscan2
- PCDHGA3 | c.2425-66847G>A | Intron (SNP) | VAF 98/634 reads (15%) | catalogued as COSV99338076, COSV99341919; called by muse, mutect2, varscan2
- PTPRT | c.2176+12050G>A | Intron (SNP) | VAF 64/249 reads (26%) | catalogued as rs951719751, COSV62005984; called by muse, mutect2, varscan2
- TCF7L2 | c.1442+682del | Intron (DEL) | VAF 22/61 reads (36%) | called by mutect2, varscan2
